CCDI case PBCLKC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/1b57c588-1ecf-4f84-8bbe-2f594f2be9f0

Demographics
Sex at birth: female; Race: asian; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.8 years (649 days).

Biospecimens (2 samples)
- Sample 0DUKHK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUKIW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
